Somatic mutation profile of tumor specimen ALCH-B0DU-TTP1-A (aliquot ALCH-B0DU-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0DU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.2 years (28,566 days).
Specimen ALCH-B0DU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f6e289a-18ba-4f82-9103-fb32d09690b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0DU-NB1-A (Blood Derived Normal), aliquot ALCH-B0DU-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d8882fd-6d9b-4127-908d-963afb9fd9ee

The open-access MAF lists 49 somatic variants for this specimen: 37 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 7, Intron 4, Frame Shift Del 2, 3'UTR 1, Splice Region 1, In Frame Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 507/1216 reads (42%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- ARHGEF4 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 82/332 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs1190892142; called by muse, mutect2, varscan2
- DEF8 | c.173+1G>A p.X58_splice | Splice Site (SNP) | VAF 14/59 reads (24%) | catalogued as rs766797171; called by muse, varscan2
- FAM20A | c.355A>G p.S119G | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs767656589; called by muse, mutect2, varscan2
- FASTKD2 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 64/328 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1290533190; called by muse, mutect2, varscan2
- JPH2 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1167554487, COSV65904277; called by muse, mutect2, varscan2
- KIF4B | c.1124G>C p.G375A | Missense Mutation (SNP) | VAF 33/589 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as rs200454857; called by muse, mutect2
- KRTAP10-5 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.023); catalogued as rs376826211; called by muse, mutect2, varscan2
- MSN | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as rs867353730; called by muse, mutect2, varscan2
- MYH6 | c.1750G>A p.A584T | Missense Mutation (SNP) | VAF 103/579 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs138317414; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA1 | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 17/451 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.604); catalogued as rs782669487, COSV65372902; called by muse, mutect2
- RBBP9 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as rs371788986; called by muse, mutect2, varscan2
- SAMD11 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs199655347; called by muse, mutect2, varscan2
- ABCD1 | c.641A>T p.N214I | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ARHGAP4 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ART1 | c.237_238del p.W79Cfs*34 | Frame Shift Del (DEL) | VAF 38/207 reads (18%) | called by mutect2, pindel, varscan2
- ATP10B | c.2901G>C p.Q967H | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- CDK10 | c.598G>C p.V200L (on ENST00000353379 / NM_052988.5; = p.V129L on NM_052987.4) | Missense Mutation (SNP) | VAF 38/375 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CLCN1 | c.2203A>G p.T735A | Missense Mutation (SNP) | VAF 40/604 reads (7%) | SIFT tolerated (0.91); PolyPhen benign (0.001); called by muse, mutect2
- COX4I2 | c.211A>G p.S71G | Missense Mutation (SNP) | VAF 34/338 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.406); called by muse, mutect2
- DMRTB1 | c.48C>A p.N16K | Missense Mutation (SNP) | VAF 129/727 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAAF1 | c.1635_1636del p.F545Lfs*3 | Frame Shift Del (DEL) | VAF 106/637 reads (17%) | called by mutect2, pindel, varscan2
- FER1L6 | c.3752A>G p.E1251G | Missense Mutation (SNP) | VAF 46/494 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- ITGA2 | c.2024T>C p.I675T | Missense Mutation (SNP) | VAF 66/612 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ITPR1 | c.1466A>G p.N489S (on ENST00000354582; = p.N474S on NM_002222.7) | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLHL5 | c.1067A>G p.Q356R | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCP2 | c.324+7A>G | Splice Region (SNP) | VAF 22/371 reads (6%) | called by muse, mutect2
- MMP14 | c.209A>G p.K70R | Missense Mutation (SNP) | VAF 35/443 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MUC2 | c.654C>G p.C218W | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); called by muse, mutect2
- OR4K15 | c.830C>A p.P277Q (on ENST00000305051; = p.P253Q on NM_001005486.1) | Missense Mutation (SNP) | VAF 27/398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR6P1 | c.745G>T p.V249F | Missense Mutation (SNP) | VAF 96/795 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- OTC | c.891C>G p.D297E | Missense Mutation (SNP) | VAF 84/620 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- PTPRU | c.182G>T p.R61L | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SERPINB2 | c.67A>T p.S23C | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2
- ZNF552 | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); called by muse, varscan2
- ZNF735 | c.1171A>T p.K391* | Nonsense Mutation (SNP) | VAF 49/295 reads (17%) | called by muse, mutect2, varscan2
- ZNF891 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.747); called by muse, varscan2
- BICRAL | c.1365C>T p.N455= | Silent (SNP) | VAF 74/582 reads (13%) | called by muse, mutect2, varscan2
- CARMIL3 | c.1905C>T p.S635= | Silent (SNP) | VAF 72/432 reads (17%) | catalogued as rs750459385, COSV57726551; called by muse, mutect2, varscan2
- CDHR2 | c.2511C>T p.D837= | Silent (SNP) | VAF 30/280 reads (11%) | called by muse, mutect2, varscan2
- FGFR3 | c.573C>T p.N191= | Silent (SNP) | VAF 12/190 reads (6%) | catalogued as rs377492283; ClinVar: likely benign; called by muse, mutect2
- GIMAP8 | c.1677C>T p.Y559= | Silent (SNP) | VAF 33/196 reads (17%) | catalogued as COSV56231721; called by muse, mutect2, varscan2
- GOLGA2 | c.33C>A p.A11= | Silent (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2
- TOM1L1 | c.12C>T p.G4= | Silent (SNP) | VAF 74/357 reads (21%) | catalogued as rs1464025073; called by muse, mutect2, varscan2
- CALR | c.91+21G>C | Intron (SNP) | VAF 23/244 reads (9%) | called by muse, mutect2, varscan2
- FXYD6-FXYD2 | c.259+3461C>A | Intron (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- NDUFA2 | c.*140C>T | 3'UTR (SNP) | VAF 97/488 reads (20%) | catalogued as rs1193403439; called by muse, mutect2, varscan2
- SNAP25 | c.164-198G>T | Intron (SNP) | VAF 16/212 reads (8%) | catalogued as COSV54773521; called by muse, mutect2
- TTN | c.35374+193G>C | Intron (SNP) | VAF 11/201 reads (5%) | called by muse, mutect2
